Somatic mutation profile of tumor specimen TCGA-EI-6884-01A (aliquot TCGA-EI-6884-01A-11D-1924-10) from TCGA case TCGA-EI-6884, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.2 years (25,995 days).
Specimen TCGA-EI-6884-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94c2c2f0-066f-462f-b307-e9272f3bb636.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6884-10A (Blood Derived Normal), aliquot TCGA-EI-6884-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b7b275b-dd7f-4aa8-8a7d-8f923a8f39db

The open-access MAF lists 115 somatic variants for this specimen: 86 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 28, Nonsense Mutation 8, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 2, Splice Region 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3190G>T p.E1064* | Nonsense Mutation (SNP) | VAF 17/127 reads (13%) | catalogued as rs1462312032, COSV57370120, COSV57397610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2
- AASDH | c.2213C>A p.A738E | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52709334; called by muse, mutect2, varscan2
- ACSM3 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.072); catalogued as COSV55503393; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1311C>A p.S437R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV58441328, COSV58445804; called by muse, mutect2, varscan2
- ADGRG5 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV61084219; called by muse, mutect2, varscan2
- ANKRD52 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV57286611; called by muse, mutect2
- ARNTL | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs949259189, COSV62988189; called by muse, mutect2, varscan2
- ASB11 | c.966C>A p.Y322* | Nonsense Mutation (SNP) | VAF 31/61 reads (51%) | catalogued as COSV60356319; called by muse, mutect2, varscan2
- ASIC2 | c.1368+2T>A p.X456_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV56768008; called by muse, mutect2
- BIRC6 | c.4205A>G p.H1402R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV70204092; called by muse, mutect2, varscan2
- CASKIN2 | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58598979; called by muse, mutect2, varscan2
- CERS3 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs142269983; called by muse, mutect2, varscan2
- CFH | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.281); catalogued as COSV66411802; called by muse, mutect2, varscan2
- CLINT1 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV51627742; called by muse, mutect2, varscan2
- CLPS | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs748533143, COSV52566647; called by muse, mutect2, varscan2
- CPT1A | c.1477A>G p.S493G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as rs1459708956, COSV55759733; called by muse, mutect2, varscan2
- CRMP1 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762086490, COSV61482244; called by muse, mutect2, varscan2
- CSMD1 | c.7937T>C p.I2646T (on ENST00000520002; = p.I2645T on NM_033225.6) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59366211; called by muse, mutect2, varscan2
- CYFIP2 | c.2851G>A p.A951T (on ENST00000616178 / NM_001291722.2; = p.A926T on NM_014376.4) | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV59032896; called by muse, mutect2, varscan2
- DHRS7C | c.476C>T p.T159M (on ENST00000330255 / NM_001220493.2; = p.T158M on NM_001105571.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs768887176, COSV57652137; called by muse, mutect2, varscan2
- DIP2C | c.1864G>A p.G622S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771008735, COSV55156559; called by muse, mutect2, varscan2
- DLC1 | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV52321300, COSV99365068; called by muse, mutect2, varscan2
- DNAH11 | c.641T>G p.I214S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV60973881; called by muse, mutect2, varscan2
- DVL1 | c.1403G>A p.R468Q (on ENST00000378888 / NM_001330311.2; = p.R443Q on NM_004421.3) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs766540058, COSV100229492; called by muse, mutect2, varscan2
- DZANK1 | c.1895C>T p.A632V (on ENST00000262547 / NM_001099407.1; = p.A439V on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV52755740; called by muse, mutect2, varscan2
- F5 | c.5115T>A p.S1705R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV63126728; called by muse, mutect2, varscan2
- FAM126B | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs536447606, COSV53773412; called by muse, mutect2, varscan2
- FAM171B | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV59007068; called by muse, mutect2, varscan2
- FAM47C | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.358); catalogued as rs782626816, COSV63727624; called by muse, mutect2, varscan2
- FANCM | c.5810G>T p.C1937F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99950956; called by muse, mutect2, varscan2
- FER | c.1428dup p.Q477Tfs*15 | Frame Shift Ins (INS) | VAF 20/110 reads (18%) | catalogued as rs1161653312; called by mutect2, varscan2
- FGF13 | c.562A>G p.N188D | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV59549197; called by muse, mutect2, varscan2
- FZD10 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1163931148, COSV57472609; called by muse, mutect2, varscan2
- HBP1 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56019020; called by muse, mutect2, varscan2
- HIP1 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.97); catalogued as rs368324123, COSV61183642; called by muse, mutect2, varscan2
- HIP1R | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368659941; called by muse, mutect2, varscan2
- IBSP | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773567537, COSV56896405; called by mutect2, varscan2
- IGSF10 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56790239; called by muse, mutect2
- IRAG1 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558392649, COSV70210812; called by muse, mutect2, varscan2
- KRT76 | c.1208A>G p.E403G | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60121584; called by muse, mutect2, varscan2
- LILRA1 | c.1408T>G p.L470V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV52183904; called by muse, mutect2, varscan2
- LRRC37A3 | c.3790G>T p.A1264S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.935); catalogued as rs146623484, COSV58536409; called by muse, mutect2, varscan2
- MBD1 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV53999446; called by muse, mutect2, varscan2
- MITF | c.554C>T p.T185M (on ENST00000448226 / NM_006722.3; = p.T79M on NM_000248.4) | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs925747808, COSV58834820; called by muse, mutect2, varscan2
- MSRB3 | c.229C>G p.H77D | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV57595739; called by muse, mutect2, varscan2
- MUC5B | c.8398G>A p.G2800S | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs371403707; called by muse, mutect2, varscan2
- NAT8 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55542930; called by muse, mutect2, varscan2
- NBAS | c.3819T>A p.G1273= | Splice Region (SNP) | VAF 11/61 reads (18%) | catalogued as COSV55733648; called by muse, mutect2, varscan2
- NEB | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV51447268; called by muse, mutect2, varscan2
- NEU3 | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53638401; called by muse, mutect2, varscan2
- NPR1 | c.2885G>A p.R962H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.66); catalogued as rs199989132, COSV64118005; called by muse, mutect2, varscan2
- OR4A15 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV59036965; called by muse, mutect2, varscan2
- PCDH10 | c.1554C>G p.I518M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs138396564, COSV52101354; called by muse, mutect2, varscan2
- PCDHA7 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as COSV65346505, COSV65348202; called by muse, mutect2
- PDZRN4 | c.2988G>T p.M996I (on ENST00000402685 / NM_001164595.2; = p.M738I on NM_013377.4) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV54211489, COSV54217404; called by muse, mutect2, varscan2
- PLCL1 | c.1768T>G p.S590A | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.085); catalogued as COSV70863592; called by muse, mutect2
- PLXNB2 | c.3466C>G p.P1156A | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63783712; called by muse, mutect2, varscan2
- POLR1A | c.2395G>A p.V799M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs567699884, COSV55697776, COSV99808556; called by mutect2, varscan2
- PRSS23 | c.883T>A p.C295S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54707389; called by muse, mutect2, varscan2
- PTPN5 | c.1654A>T p.M552L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60037385; called by muse, mutect2, varscan2
- RADIL | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753252335, COSV68202264; called by muse, mutect2, varscan2
- RYR2 | c.6231C>A p.D2077E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs1407541809, COSV63705773; called by muse, mutect2, varscan2
- SCN11A | c.2944C>T p.R982* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as rs145290679, COSV56569403; called by muse, mutect2, varscan2
- SETD4 | c.1253G>A p.W418* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV59773482; called by muse, mutect2
- SLAIN2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs866212190, COSV99971622; called by muse, mutect2
- SLC4A11 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.479); catalogued as rs772271724, COSV101196101, COSV66261620; called by muse, mutect2, varscan2
- SON | c.6056G>A p.R2019Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1278416107, COSV51663790; called by muse, mutect2
- TENM4 | c.2597A>G p.N866S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760415394, COSV53611118, COSV53618741, COSV99581394; called by muse, mutect2
- TIGAR | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV99463609; called by mutect2, varscan2
- TLR3 | c.1886T>C p.V629A | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99710960; called by muse, mutect2, varscan2
- TSPEAR | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 13/347 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs949831951, COSV99043061; called by muse, mutect2
- TTN | c.13808C>T p.T4603M (on ENST00000591111; = p.T3676M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | PolyPhen benign (0.014); catalogued as rs371455094; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TUBA3C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 215/402 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as rs748945233, COSV67139000, COSV67139414; called by muse, mutect2, varscan2
- ZMAT1 | c.1790A>T p.K597I | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65659676; called by muse, varscan2
- ZMAT1 | c.1789A>T p.K597* | Nonsense Mutation (SNP) | VAF 56/162 reads (35%) | catalogued as COSV65659684; called by muse, varscan2
- ZNF546 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1425316267, COSV61259119; called by muse, mutect2
- ZNF804B | c.1687A>T p.K563* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV60826438; called by muse, mutect2, varscan2
- ZNF836 | c.2617C>T p.R873W | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as rs750525227, COSV59081627; called by muse, mutect2, varscan2
- AKAP6 | c.6346_6347del p.S2116Ifs*3 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by pindel, varscan2
- APC | c.4738_4741del p.I1580Lfs*69 | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.2828_2829insCCTAGA p.D941_L942dup | In Frame Ins (INS) | VAF 5/51 reads (10%) | called by muse*, mutect2, varscan2*
- PRSS12 | c.2542_2545dup p.G849Vfs*98 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- RASSF10 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNTG1 | c.1271A>T p.D424V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- THUMPD2 | c.408dup p.V137Sfs*5 | Frame Shift Ins (INS) | VAF 42/257 reads (16%) | called by mutect2, pindel, varscan2
- ALPK2 | c.1542G>A p.T514= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs749206916, COSV64494486; called by muse, mutect2, varscan2
- CASQ1 | c.1149C>T p.G383= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs760098501, COSV63623426; called by muse, mutect2, varscan2
- CDH22 | c.381C>T p.R127= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs143379744; called by muse, mutect2, varscan2
- COQ5 | c.57G>A p.R19= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99942285; called by muse, mutect2, varscan2
- CPT1A | c.1476C>T p.D492= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV55759754; called by muse, mutect2, varscan2
- DACT1 | c.1551C>T p.G517= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1197675702, COSV60021902; called by muse, mutect2, varscan2
- DCAF12L1 | c.1065G>A p.S355= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100948117, COSV64422566; called by muse, mutect2, varscan2
- DLX5 | c.90G>A p.P30= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV56033892; called by muse, mutect2, varscan2
- DMXL2 | c.9019C>A p.R3007= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV51853334; called by muse, mutect2, varscan2
- EGFLAM | c.1101G>A p.S367= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs771843048, COSV59294175; called by muse, mutect2, varscan2
- FAM135B | c.2043C>T p.S681= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs759228176, COSV52746354; called by muse, mutect2, varscan2
- FAM184A | c.513C>T p.S171= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV58857494; called by muse, mutect2, varscan2
- HECTD4 | c.1552C>T p.L518= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV66397531; called by muse, mutect2, varscan2
- HSPA12A | c.342C>T p.F114= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs374384405; called by muse, mutect2, varscan2
- IRGQ | c.1131G>T p.S377= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV60671282; called by muse, mutect2, varscan2
- ITGAL | c.2220G>A p.P740= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as rs754571775, COSV63323289; called by muse, mutect2, varscan2
- KIF1B | c.4713C>T p.I1571= (on ENST00000377086 / NM_001365952.1; = p.I1525= on NM_015074.3) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs750386624, COSV55813888; called by muse, mutect2, varscan2
- KRT37 | c.273C>T p.I91= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV56659547; called by muse, mutect2
- LRRC4C | c.150G>A p.V50= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV53434970; called by mutect2, varscan2
- MED12L | c.1011C>T p.P337= | Silent (SNP) | VAF 84/176 reads (48%) | catalogued as rs368805516, COSV56370801; called by muse, mutect2, varscan2
- OR6K6 | c.585T>G p.P195= (on ENST00000368144; = p.P171= on NM_001005184.1) | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV63744694; called by muse, mutect2, varscan2
- PCOLCE2 | c.441C>T p.N147= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs753153268, COSV56001253, COSV99930916; called by muse, mutect2, varscan2
- SGK3 | c.642C>A p.L214= | Silent (SNP) | VAF 31/195 reads (16%) | catalogued as COSV100616676; called by muse, mutect2, varscan2
- TTN | c.46410C>T p.L15470= (on ENST00000591111; = p.L8046= on NM_003319.4) | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV59966460, COSV60264641; called by muse, mutect2, varscan2
- USH2A | c.13905A>G p.Q4635= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV56416832; called by muse, mutect2, varscan2
- ZBTB1 | c.1611T>G p.P537= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV62438397, COSV62439484; called by muse, mutect2, varscan2
- ZFP42 | c.870T>C p.N290= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100478814; called by muse, mutect2, varscan2
- ZMAT1 | c.1791A>G p.K597= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as COSV65658297; called by muse, varscan2
- MIRLET7C | n.65C>T | RNA (SNP) | VAF 51/181 reads (28%) | called by muse, mutect2, varscan2
